Somatic mutation profile of tumor specimen TARGET-30-PASCZY-01A (aliquot TARGET-30-PASCZY-01A-01D) from TARGET case TARGET-30-PASCZY, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 1.3 years (493 days).
Specimen TARGET-30-PASCZY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3490c785-6482-49cc-a538-0334725cd686.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASCZY-10A (Blood Derived Normal), aliquot TARGET-30-PASCZY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5f0cf88-6670-44d5-b4c9-d86db0c17ec9

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3733T>A p.F1245I | Missense Mutation (SNP) | VAF 60/141 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs281864720, CM113794, COSV66555887, COSV66558742; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.4660G>T p.E1554* | Nonsense Mutation (SNP) | VAF 30/134 reads (22%) | catalogued as rs1392778905, CD130102, COSV57329463, COSV57332231; ClinVar: pathogenic; called by muse, mutect2, varscan2
